Surgical pathology report (de-identified scan), TCGA case TCGA-24-1427, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Washington University, specimen TCGA-24-1427-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT
FINAL WITH ADDENDUM

TCGA-24-
1427

Patient Name:

Address:

Gender:

DOB:

Service:

Location:

MRN:

Hospital #:

Patient Type:

Accession #:

Taken:

Received:

Accessioned:

Reported:

Physician(s):

DIAGNOSIS:

OVARY, RIGHT, SALPINGO-OOPHORECTOMY

- SEROUS CARCINOMA, HIGH GRADE
- TUMOR INVOLVES OVARIAN PARENCHYMA AND SURFACE
- PARAOVARIAN ADHESIONS WITH ASSOCIATE CARCINOMA

FALLOPIAN TUBE, RIGHT, SALPINGO-OOPHORECTOMY

- METASTATIC SEROUS CARCINOMA, HIGH GRADE, INVOLVING SEROSAL SURFACE AND PERITUBAL SOFT TISSUE
- FALLOPIAN TUBE EPITHELIUM AND MUSCULAR WALL FREE OF TUMOR
- TUBO-OVARIAN ADHESIONS

OVARY, LEFT, SALPINGO-OOPHORECTOMY

- SEROUS CARCINOMA, HIGH GRADE
- TUMOR INVOLVES OVARIAN PARENCHYMA AND SURFACE
- PARAOVARIAN ADHESIONS WITH ASSOCIATED CARCINOMA

FALLOPIAN TUBE, LEFT, SALPINGO-OOPHORECTOMY

- METASTATIC SEROSAL CARCINOMA, HIGH GRADE

UTERUS, CERVIX, TOTAL ABDOMINAL HYSTERECTOMY

- CHRONIC INFLAMMATION (SEE COMMENT)

UTERUS, ENDOMETRIUM, TOTAL ABDOMINAL HYSTERECTOMY

- INACTIVE ENDOMETRIUM

UTERUS, MYOMETRIUM, TOTAL ABDOMINAL HYSTERECTOMY

- METASTATIC SEROUS CARCINOMA BY DIRECT EXTENSION FROM SEROSAL IMPLANT
- EXTENSIVE LYMPHAVASCULAR SPACE INVASION BY SEROUS CARCINOMA

UTERUS, SEROSA, TOTAL ABDOMINAL HYSTERECTOMY

- METASTATIC SEROUS CARCINOMA

OMENTUM, EXCISION

- EXTENSIVE METASTATIC SEROUS CARCINOMA

[page 2 of 3]
SYNOPTIC REPORTING FORM FOR MALIGNANT OVARIAN NEOPLASMS

HISTOPATHOLOGIC TYPE

The histologic diagnosis is serous adenocarcinoma

TUMOR LOCATION

The locations of the primary tumor(s) are the right and left ovary (synchronous primary tumors)

HISTOLOGIC GRADE

The histologic grade is poorly differentiated (G3)

TUMOR INVASION

Tumor is identified on the ovarian surface(s)

TUMOR INVOLVEMENT

Tumor involvement of the pelvic peritoneum/soft tissue is present

Metastatic involvement of the omentum is present

TUMOR SIZE

The maximum dimension of tumor implants outside the true pelvis is greater than or equal to 2 cm

PRIMARY TUMOR (T)

Based on the above information, the primary tumor is classified as macroscopic peritoneal metastasis beyond pelvis more than 2 cm in greatest dimension or regional lymph node metastasis (T3c/IIIC)

REGIONAL LYMPH NODES (N)

The regional lymph nodes cannot be assessed

DISTANT METASTASIS (M)

The status of distant tumor site cannot be assessed

STAGE GROUPING

The Final AJCC/UICC/FIGO stage is T3c/NX/MX

The pathologic stage assigned here should be regarded as provisional, and may change after integration of clinical data not provided with this specimen.

Addendum Comment

Additional sections of posterior cervix have been submitted in cassettes labeled A11 through A15. These slides do show squamous epithelium indicative of ectocervix. In addition, serous carcinoma is present at the deep soft tissue resection margin.

Source: NCI Genomic Data Commons file ba5f8659-5b87-4976-89a7-037d8061e23b (TCGA-24-1427.AF63C4E2-2F77-4311-BFE2-EE45CFD200BB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).